Somatic mutation profile of tumor specimen TCGA-EM-A4FF-01A (aliquot TCGA-EM-A4FF-01A-11D-A257-08) from TCGA case TCGA-EM-A4FF, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 40.5 years (14,796 days).
Specimen TCGA-EM-A4FF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80eac69f-4cef-4793-820e-59b6f7602f56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A4FF-10A (Blood Derived Normal), aliquot TCGA-EM-A4FF-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f18e756-fb41-45ac-a0ed-a3bf29000ade

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ALX3 | c.397C>T p.H133Y | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs761160635, COSV100873863; called by muse, mutect2, varscan2
- ANKZF1 | c.559-2A>G p.X187_splice | Splice Site (SNP) | VAF 65/186 reads (35%) | catalogued as COSV99850225; called by muse, mutect2, varscan2
- KCNJ10 | c.699G>C p.Q233H | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100927860; called by muse, mutect2, varscan2
- PLXNA3 | c.4936G>A p.G1646S | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV100859792; called by muse, mutect2, varscan2
- VCP | c.1106T>C p.I369T | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100734085; called by muse, mutect2, varscan2
- NSUN3 | c.128_129del p.I43Tfs*14 | Frame Shift Del (DEL) | VAF 11/65 reads (17%) | called by mutect2, pindel, varscan2
